CCDI case PBBUAF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasal cavity and middle ear.
https://portal.gdc.cancer.gov/cases/6a710a0e-b958-4167-93aa-0c6b597ec64e

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Ethmoid sinus; Age at diagnosis: 12.6 years (4,612 days).

Biospecimens (3 samples)
- Sample 0DMINY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMIOG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DMIPF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
